Somatic mutation profile of tumor specimen TCGA-EM-A3O8-01A (aliquot TCGA-EM-A3O8-01A-11D-A21Z-08) from TCGA case TCGA-EM-A3O8, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 34.0 years (12,405 days).
Specimen TCGA-EM-A3O8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d90681a0-aa88-4082-ad2d-66294ee4ff71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3O8-10A (Blood Derived Normal), aliquot TCGA-EM-A3O8-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2706f906-dafe-404d-8d4f-87bda79abd67

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GFI1 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54044165; called by muse, mutect2, varscan2
- MOV10 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 70/158 reads (44%) | catalogued as COSV62492849; called by muse, mutect2, varscan2
- ZNF169 | c.1464C>T p.C488= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV61766973; called by muse, mutect2, varscan2
